Somatic mutation profile of tumor specimen TCGA-EL-A3T8-01A (aliquot TCGA-EL-A3T8-01A-21D-A22D-08) from TCGA case TCGA-EL-A3T8, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 36.4 years (13,290 days).
Specimen TCGA-EL-A3T8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e4a40e7-90f7-4bee-b7e1-750b4215a27d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3T8-11A (Solid Tissue Normal), aliquot TCGA-EL-A3T8-11A-11D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20fad976-1d4b-410d-9efe-28147b03047b

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ATP6V1C1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV67777823; called by muse, mutect2
- FAM117B | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57418330; called by muse, mutect2
- FECH | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV50490660; called by muse, mutect2
- ZDBF2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0.103); catalogued as rs779996852, COSV65621430, COSV65629627; called by muse, mutect2, varscan2
- SFMBT2 | c.1503G>T p.V501= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV62808163; called by muse, mutect2, varscan2
